Somatic mutation profile of tumor specimen MP2PRT-PASNSJ-TMP1-A (aliquot MP2PRT-PASNSJ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNSJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,707 days).
Specimen MP2PRT-PASNSJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a121fef2-599e-4cce-b937-bc9fd910ec1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNSJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNSJ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42d319f8-3bf5-4537-a7ae-578df3fc7324

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 33/363 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ERLIN1 | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PAPPA2 | c.1052C>G p.T351S | Missense Mutation (SNP) | VAF 138/407 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZNF462 | c.2899C>A p.Q967K | Missense Mutation (SNP) | VAF 109/423 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDSN | c.1284C>T p.T428= | Silent (SNP) | VAF 233/817 reads (29%) | catalogued as rs758172158; called by muse, mutect2, varscan2
- GJA8 | c.519C>T p.Y173= | Silent (SNP) | VAF 153/476 reads (32%) | catalogued as rs782648768, COSV53787636; called by muse, mutect2, varscan2
- SBNO2 | c.3981G>A p.P1327= | Silent (SNP) | VAF 40/397 reads (10%) | catalogued as rs1167678881; called by muse, mutect2, varscan2
